Gene-level copy-number profile of tumor specimen REBC-ACAC-TTP1-A from REBC case REBC-ACAC, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACAC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d57f3aa5-3ca3-4fbd-81f5-eefce7482dae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACAC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/36efc5c7-b2b2-4890-88d2-2961a7b86258

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 175; copy number 2: 58,168; copy number 3: 49; copy number 4: 5; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:58,999,482–59,066,396, 1 gene: LINC00844.
- chr16:88,936,779–88,951,524, 2 genes (within-gene range 0–2): AC092384.3, AC092384.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:42,500,568–42,512,560, 1 gene, copy number 5 (within-gene range 2–5): SERHL.

Autosomal genes at a single copy (total copy number 1): 175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
